Somatic mutation profile of tumor specimen TCGA-AR-A0TR-01A (aliquot TCGA-AR-A0TR-01A-11D-A099-09) from TCGA case TCGA-AR-A0TR, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 69.0 years (25,190 days).
Specimen TCGA-AR-A0TR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c4b61313-5bc5-46d1-9790-5e6e7e47a58b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AR-A0TR-10A (Blood Derived Normal), aliquot TCGA-AR-A0TR-10A-01D-A099-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/39eb14db-745e-41ac-97b9-91c76b214a60

The open-access MAF lists 37 somatic variants for this specimen: 27 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 22, Silent 10, Frame Shift Del 2, Frame Shift Ins 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1035T>A p.N345K | Missense Mutation (SNP) | VAF 25/66 reads (38%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs121913284, COSV55873276; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACADSB | c.17T>C p.V6A | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as rs1454409025, COSV100715227; called by mutect2, varscan2
- ADAMTSL3 | c.957C>G p.F319L | Missense Mutation (SNP) | VAF 30/54 reads (56%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as rs763892662, COSV99719504, COSV99720912; called by muse, mutect2, varscan2
- ARHGEF40 | c.4459dup p.H1487Pfs*28 | Frame Shift Ins (INS) | VAF 16/102 reads (16%) | catalogued as rs758492903; called by mutect2, varscan2
- ATN1 | c.605C>T p.T202I | Missense Mutation (SNP) | VAF 28/46 reads (61%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs781803346, COSV100755833; called by muse, varscan2
- C16orf54 | c.4C>A p.P2T | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.347); catalogued as COSV100268500; called by muse, varscan2
- C17orf67 | c.203A>G p.Q68R | Missense Mutation (SNP) | VAF 25/126 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.422); catalogued as rs775996754, COSV101190984; called by muse, mutect2, varscan2
- FAM110A | c.55C>T p.R19C | Missense Mutation (SNP) | VAF 8/10 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs529130062, COSV99856753; called by muse, mutect2
- FCRL5 | c.297T>A p.D99E | Missense Mutation (SNP) | VAF 88/160 reads (55%) | SIFT tolerated (0.38); PolyPhen benign (0.012); catalogued as COSV100709022; called by muse, mutect2, varscan2
- FPR3 | c.734C>T p.A245V | Missense Mutation (SNP) | VAF 155/352 reads (44%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.824); catalogued as COSV100200779; called by muse, mutect2
- ITGA6 | c.308C>T p.A103V | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.777); catalogued as COSV99905638; called by muse, mutect2, varscan2
- ITSN1 | c.4273C>T p.R1425W | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs187930521, COSV101182079; called by muse, mutect2, varscan2
- KIFBP | c.526G>T p.V176F | Missense Mutation (SNP) | VAF 51/248 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.033); catalogued as rs757109189, COSV100741405; called by muse, mutect2, varscan2
- MADD | c.4817G>A p.S1606N | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.543); catalogued as COSV99920541; called by muse, mutect2, varscan2
- MORN1 | c.1187C>T p.S396F | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.271); catalogued as COSV101047968; called by muse, mutect2, varscan2
- MYO1F | c.2875C>A p.P959T | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs776630100, COSV100596789; called by muse, mutect2, varscan2
- NIBAN2 | c.1460T>A p.V487E | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100031612; called by muse, mutect2, varscan2
- PMS1 | c.1472C>T p.S491L | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs753545002, COSV100575694; called by muse, mutect2, varscan2
- SLC17A7 | c.1217C>T p.S406F | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as COSV99676905; called by muse, mutect2
- USP53 | c.884T>A p.I295N | Missense Mutation (SNP) | VAF 52/151 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99917818; called by muse, mutect2, varscan2
- XPO7 | c.3208A>G p.N1070D | Missense Mutation (SNP) | VAF 47/161 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.052); catalogued as COSV99381499, COSV99382118; called by muse, mutect2
- ZFP42 | c.899C>T p.A300V | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as rs1161144629, COSV100478953, COSV58818534; called by muse, mutect2, varscan2
- ZFP82 | c.1423G>A p.E475K | Missense Mutation (SNP) | VAF 64/177 reads (36%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs1021451717, COSV101089133; called by muse, mutect2, varscan2
- APLP2 | c.1615del p.R539Gfs*15 | Frame Shift Del (DEL) | VAF 37/109 reads (34%) | called by mutect2, pindel, varscan2
- LIN9 | c.1526_1528del p.E509del (on ENST00000366808 / NM_001270410.2; = p.E454del on NM_173083.3 and 5 other RefSeq transcripts) | In Frame Del (DEL) | VAF 38/295 reads (13%) | called by pindel, varscan2
- METTL2A | c.624dup p.V209Cfs*5 | Frame Shift Ins (INS) | VAF 86/734 reads (12%) | called by pindel, varscan2
- NELL2 | c.1240del p.R414Efs*3 | Frame Shift Del (DEL) | VAF 19/142 reads (13%) | called by mutect2, pindel, varscan2
- ADCY6 | c.3189C>G p.A1063= | Silent (SNP) | VAF 42/120 reads (35%) | catalogued as COSV100326693; called by muse, mutect2, varscan2
- ARL6IP6 | c.420G>A p.L140= | Silent (SNP) | VAF 88/464 reads (19%) | catalogued as COSV100424039; called by muse, mutect2, varscan2
- DYTN | c.258G>A p.P86= | Silent (SNP) | VAF 24/133 reads (18%) | catalogued as rs747863949, COSV101510795; called by muse, mutect2, varscan2
- MAP4 | c.1893G>A p.T631= | Silent (SNP) | VAF 59/304 reads (19%) | catalogued as rs774227826, COSV99275631; called by muse, mutect2, varscan2
- PAPOLA | c.1962A>G p.S654= | Silent (SNP) | VAF 53/67 reads (79%) | catalogued as COSV99354345; called by muse, mutect2, varscan2
- RNF175 | c.195T>C p.I65= | Silent (SNP) | VAF 21/62 reads (34%) | catalogued as COSV99924160; called by muse, mutect2, varscan2
- RPL7L1 | c.195A>T p.L65= | Silent (SNP) | VAF 64/172 reads (37%) | catalogued as COSV100491722; called by muse, mutect2, varscan2
- SERPINB6 | c.729T>A p.V243= (on ENST00000612421 / NM_001271823.2; = p.V224= on NM_004568.6) | Silent (SNP) | VAF 64/183 reads (35%) | catalogued as COSV100177535; called by muse, mutect2, varscan2
- SMYD1 | c.438C>T p.D146= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as COSV101352457; called by muse, mutect2, varscan2
- STAB1 | c.6708C>T p.V2236= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as rs753914033, COSV100195120; called by muse, mutect2, varscan2
